Gene-level copy-number profile of tumor specimen TCGA-LN-A4A6-01A from TCGA case TCGA-LN-A4A6, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.7 years (24,011 days).
Specimen TCGA-LN-A4A6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.96054d42-2831-4e3f-b4d0-cd1f362ed51f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A4A6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/d5591ee1-f3c4-49a2-b502-f3731c5d679c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 198; copy number 1: 3; copy number 2: 18,102; copy number 3: 20,312; copy number 4: 16,746; copy number 5: 3,019; copy number 6: 1,046; copy number 7: 117; copy number 8: 14; copy number 9: 114; copy number 12: 41; copy number 16: 106.

Homozygous deletions (total copy number 0; autosomes only): 198 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:141,074,064–141,551,304, 8 genes (within-gene range 0–2): TMEM178B, AC006362.1, NDUFB10P2, AC005692.3, AC005692.1, AC005692.2, AC073878.1, AC073878.2.
- chr9:21,453,802–31,645,160, 100 genes (broad region; genes not listed).
- chr13:57,140,918–68,037,131, 90 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 392 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:18,547,312–30,743,704, 112 genes, copy number 7 (broad region; genes not listed).
- chr5:53,206,561–53,683,338, 5 genes, copy number 7 (within-gene range 3–7): AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4.
- chr7:101,287,482–102,616,756, 41 genes, copy number 12 (within-gene range 6–12): AZGP1P2, LNCPRESS1, EMSLR, IFT22, COL26A1, AC004965.1, LINC01007, MYL10, CUX1, AC005096.1, AC005072.1, AC005086.2, AC005086.5, AC005086.4, AC005086.3, AC005086.1, AC005088.1, SH2B2, MIR4285, AC091390.1, Y_RNA, PMS2P12, SPDYE6, PRKRIP1, AC091390.3, AC091390.2, MIR548O, AC073517.1, ORAI2, ALKBH4, LRWD1, MIR5090, MIR4467, POLR2J, RASA4B, POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3, RASA4.
- chr11:67,483,026–73,662,819, 220 genes, copy number 9–16 (broad region; genes not listed).
- chr18:34,493,290–35,328,390, 14 genes, copy number 8 (within-gene range 2–8): DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
